Somatic mutation profile of tumor specimen TCGA-R6-A8W8-01B (aliquot TCGA-R6-A8W8-01B-11D-A37C-09) from TCGA case TCGA-R6-A8W8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 72.6 years (26,535 days).
Specimen TCGA-R6-A8W8-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6ed5110-7de0-47fc-a33b-ebe8f24c6f5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A8W8-10A (Blood Derived Normal), aliquot TCGA-R6-A8W8-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e90a7b5d-b4d3-4885-9597-d7b537ed91c7

The open-access MAF lists 150 somatic variants for this specimen: 111 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 36, Frame Shift Del 6, Nonsense Mutation 4, In Frame Del 2, Frame Shift Ins 2, Intron 1, RNA 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as rs1567556930, COSV52694020, COSV53536519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARD | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs542421964, COSV65599658; called by muse, mutect2, varscan2
- AARS2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs771082902, COSV99771395; called by muse, mutect2, varscan2
- ACSF2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as rs749125979; called by muse, mutect2, varscan2
- AL592490.1 | c.1667A>C p.K556T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.783); catalogued as COSV69426541; called by muse, mutect2, varscan2
- BRCA2 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507832, CS129232; ClinVar: not provided; called by mutect2, varscan2
- C12orf56 | c.1285C>T p.R429C (on ENST00000543942 / NM_001170633.2; = p.R269C on NM_001099676.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs780945635, COSV61485974; called by muse, mutect2, varscan2
- C8B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs375318933; called by muse, mutect2, varscan2
- CACNA1I | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as rs769561916, COSV60800640; called by muse, mutect2, varscan2
- CBX8 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV53936230; called by muse, mutect2, varscan2
- CCER1 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100726964; called by muse, mutect2, varscan2
- CCT8L2 | c.709A>C p.S237R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV63463328; called by muse, mutect2, varscan2
- CFH | c.2566G>A p.G856R | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1184821060, COSV100809120; called by muse, mutect2, varscan2
- CGNL1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs778369167; called by muse, mutect2, varscan2
- CNGB3 | c.477A>C p.E159D | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV60686870; called by muse, mutect2, varscan2
- CNTNAP5 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as rs760438818, COSV70470252; called by muse, mutect2, varscan2
- COL5A1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs144269434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs777945397; called by mutect2, varscan2
- CYP21A2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771822460, CM052844; called by muse, mutect2, varscan2
- DLGAP2 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs764298685; called by muse, mutect2, varscan2
- DPEP3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs771035829, COSV52050838; called by muse, mutect2, varscan2
- E2F7 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs779479853, COSV59739166; called by muse, mutect2, varscan2
- GALNT13 | c.1110A>C p.E370D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV67214528; called by muse, mutect2, varscan2
- GDPD4 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1342637068; called by muse, mutect2, varscan2
- GPR50 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as rs367648979; called by muse, varscan2
- GRM8 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs781604600; called by muse, mutect2, varscan2
- HIVEP2 | c.6908G>A p.R2303Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs1371941401, COSV50012109; called by muse, mutect2, varscan2
- IGKV2D-30 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs368396735; called by muse, mutect2, varscan2
- ITGA8 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as rs141621826; called by muse, mutect2, varscan2
- KMT2C | c.5957G>A p.R1986Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs138373177; called by muse, mutect2, varscan2
- LLGL1 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs572067853; called by muse, mutect2, varscan2
- MAGEE2 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1287963635; called by muse, mutect2, varscan2
- MEGF8 | c.6892A>C p.T2298P (on ENST00000251268 / NM_001271938.2; = p.T2231P on NM_001410.3) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs776168721; called by muse, mutect2, varscan2
- NCOR2 | c.4846C>T p.R1616W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs944324049; called by muse, mutect2, varscan2
- OLFM1 | c.824G>A p.R275H (on ENST00000371793 / NM_001282611.2; = p.R257H on NM_014279.5) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs762963863; called by mutect2, varscan2
- PAK6 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); catalogued as rs775883867, COSV99544307; called by muse, mutect2, varscan2
- PCDHA7 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV65342050; called by muse, mutect2, varscan2
- PCDHB3 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs1554272093, COSV50582868; called by muse, mutect2, varscan2
- PINK1 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs574890623, CM158495, COSV58632188; called by muse, mutect2, varscan2
- PRICKLE1 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1323129125, COSV58210079; called by muse, mutect2, varscan2
- PROS1 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs199469495, CM136312; called by muse, mutect2, varscan2
- RASEF | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1314704396; called by muse, mutect2
- RSPH3 | c.1207C>T p.R403C (on ENST00000252655; = p.R261C on NM_031924.8) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs755422448, COSV51921221; called by muse, mutect2, varscan2
- RYR3 | c.14138C>T p.T4713M (on ENST00000389232; = p.T4714M on NM_001036.6) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV101211892; called by muse, mutect2, varscan2
- SCN11A | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753507140, COSV56574301; called by muse, mutect2, varscan2
- SEC23B | c.2129C>T p.T710M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752664090, CM110740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66802674; called by muse, mutect2, varscan2
- SPHK2 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs1416909195; called by muse, mutect2, varscan2
- SRGAP3 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs754930892; called by muse, mutect2, varscan2
- TENM3 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs1389600882; called by muse, varscan2
- TPO | c.2127C>G p.F709L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199561216; called by muse, mutect2, varscan2
- TSKS | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs938397628, COSV104370647, COSV55872740; called by muse, mutect2, varscan2
- TTN | c.43760G>A p.R14587H (on ENST00000591111; = p.R7163H on NM_003319.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | PolyPhen probably damaging (0.998); catalogued as rs368806005; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZBTB16 | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100251911, COSV60090006, COSV60099514; called by muse, varscan2
- ZNF835 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs575232626, COSV101606360; called by muse, mutect2, varscan2
- ADRM1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- AMBRA1 | c.228del p.N76Kfs*7 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- BTN3A1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA2D1 | c.3295A>C p.T1099P (on ENST00000356253 / NM_001366867.1; = p.T1087P on NM_000722.4) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH20 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CDHR2 | c.2962_2970del p.S988_F990del | In Frame Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- CLEC4A | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNOT6 | c.1323G>T p.R441S | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.77); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CTNND2 | c.2860G>T p.A954S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF12L1 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DPP6 | c.650G>T p.G217V (on ENST00000377770 / NM_001364500.2; = p.G155V on NM_001936.5) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- EMILIN3 | c.1993G>A p.V665M | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENAH | c.1757G>A p.S586N (on ENST00000366844 / NM_001008493.3; = p.S565N on NM_018212.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ERCC6L2 | c.359_387del p.N120Rfs*19 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- GMIP | c.1752C>T p.G584= | Splice Region (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- GRIN2B | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2BW1 | c.110C>A p.T37N | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- HEATR4 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 65/158 reads (41%) | called by muse, mutect2, varscan2
- HIVEP2 | c.6196C>T p.P2066S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); called by muse, mutect2
- KCNQ3 | c.1912T>C p.F638L | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KNDC1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- LRRC37A | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LRRC37A | c.4299C>A p.N1433K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MAGEB1 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- MDGA2 | c.2317T>G p.L773V (on ENST00000399232 / NM_001113498.2; = p.L475V on NM_182830.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKRN3 | c.343T>C p.C115R | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYCBP2 | c.8170G>A p.E2724K (on ENST00000357337; = p.E2762K on NM_015057.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NAV3 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- NCOR2 | c.4047C>A p.H1349Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- NID2 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- NINL | c.3349_3350del p.Q1117Efs*5 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- NPEPL1 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- NRP1 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR2AE1 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PDZD4 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.025); called by muse, mutect2
- PER2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PER3 | c.3346C>G p.L1116V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PIM3 | c.703_705del p.L235del | In Frame Del (DEL) | VAF 13/27 reads (48%) | called by mutect2, pindel, varscan2
- PKD1L1 | c.4477G>A p.G1493S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLEKHA3 | c.5_21del p.E2Vfs*17 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- PPP1R3A | c.3365A>C p.K1122T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PRAMEF15 | c.113del p.F38Sfs*17 | Frame Shift Del (DEL) | VAF 43/237 reads (18%) | called by mutect2, pindel, varscan2
- RIOK3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPA1 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- RTTN | c.3919dup p.Y1307Lfs*30 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- SF3A1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SRRM4 | c.1721G>T p.S574I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ST8SIA5 | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 13/32 reads (41%) | PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SYNE1 | c.4769A>C p.K1590T (on ENST00000367255 / NM_182961.4; = p.K1597T on NM_033071.3) | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SYT10 | c.787T>C p.F263L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TENM3 | c.415del p.V139Sfs*19 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | called by pindel, varscan2
- TNFRSF8 | c.883A>G p.N295D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- TRRAP | c.8644T>C p.W2882R (on ENST00000359863 / NM_001244580.1; = p.W2864R on NM_003496.3) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TSC1 | c.2399T>G p.L800R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ZNF131 | c.1739G>A p.S580N (on ENST00000509156 / NM_001330707.2; = p.S546N on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY3 | c.1359C>T p.R453= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs755866000, COSV53165971, COSV53174611; called by muse, mutect2, varscan2
- BRINP1 | c.2190G>A p.L730= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- BSDC1 | c.381G>A p.S127= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs771789900; called by muse, mutect2, varscan2
- CAMK1D | c.942C>T p.A314= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs771342663; called by muse, mutect2
- CFHR5 | c.667A>C p.R223= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56822359; called by muse, mutect2, varscan2
- CRYZ | c.651A>T p.G217= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.1185G>A p.P395= | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- DNAI4 | c.2451T>A p.S817= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- DNAJB2 | c.891G>A p.G297= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1186643670; called by muse, mutect2, varscan2
- DPP4 | c.1359G>A p.R453= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- DSC3 | c.1776C>T p.T592= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs139705637, COSV100844666; called by muse, mutect2, varscan2
- FASTKD3 | c.429G>A p.K143= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- FBLN2 | c.2544C>T p.H848= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs761995630, COSV55481138; called by muse, mutect2, varscan2
- GABRA6 | c.1155C>T p.S385= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs775737124, COSV50877479; called by muse, mutect2, varscan2
- HGS | c.1233G>A p.A411= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1413789790, COSV61269626; called by muse, mutect2, varscan2
- ITGAL | c.528G>A p.L176= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV63320010; called by mutect2, varscan2
- KCNJ12 | c.579G>A p.T193= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs782637855, COSV59165750; called by muse, mutect2, varscan2
- LHPP | c.768C>T p.N256= | Silent (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- LRRC8B | c.1341G>A p.L447= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- MCRS1 | c.744G>A p.A248= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1387119924; called by muse, mutect2, varscan2
- PHF2 | c.2100G>A p.P700= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs768589231, COSV63683826; called by muse, mutect2, varscan2
- PPP1R26 | c.2706C>T p.A902= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs372949310; called by muse, mutect2, varscan2
- RYR1 | c.12555G>A p.A4185= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1442355076, COSV62108558; called by muse, mutect2, varscan2
- SCEL | c.498G>T p.P166= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- SCN2A | c.2715G>A p.K905= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as CM136051; called by muse, mutect2, varscan2
- SIGLEC7 | c.291C>A p.L97= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- SIX3 | c.897G>A p.T299= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99578412; called by muse, mutect2, varscan2
- SLC30A8 | c.900G>A p.V300= | Silent (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- TRIM42 | c.819A>G p.Q273= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1357251584; called by muse, mutect2, varscan2
- TTC37 | c.1651C>T p.L551= | Silent (SNP) | VAF 17/22 reads (77%) | called by muse, mutect2, varscan2
- USP32 | c.363C>T p.H121= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs375435948; called by muse, mutect2, varscan2
- WDR81 | c.4800C>T p.N1600= (on ENST00000409644 / NM_001163809.2; = p.N549= on NM_152348.4) | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as rs753656730; called by muse, mutect2, varscan2
- ZBTB16 | c.1707G>A p.T569= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100251956; called by muse, varscan2
- ZIC3 | c.1002C>A p.G334= | Silent (SNP) | VAF 9/12 reads (75%) | called by muse, varscan2
- ZNF256 | c.1338G>A p.R446= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV56599071; called by muse, mutect2
- ZNF429 | c.993T>C p.H331= | Silent (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- PIGK | c.987-6983C>G | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as rs766600467; called by mutect2, varscan2
- RN7SL176P | chr12:100157649 G>T | 3'Flank (SNP) | VAF 12/44 reads (27%) | catalogued as rs1357755932; called by muse, mutect2, varscan2
- VN1R10P | n.476_477del | RNA (DEL) | VAF 22/43 reads (51%) | catalogued as rs1453523254; called by mutect2, pindel, varscan2
